Somatic mutation profile of tumor specimen TCGA-55-7283-01A (aliquot TCGA-55-7283-01A-11D-2036-08) from TCGA case TCGA-55-7283, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Bronchiolo-alveolar carcinoma, non-mucinous; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 76.5 years (27,946 days).
Specimen TCGA-55-7283-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 49c7ed58-80e9-4cae-924b-6887da02522c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-55-7283-10A (Blood Derived Normal), aliquot TCGA-55-7283-10A-01D-2036-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/14634f3e-3e1a-45db-8f70-0861a361b6aa

The open-access MAF lists 234 somatic variants for this specimen: 178 protein-altering or splice-affecting, 51 silent, 5 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 152, Silent 51, Nonsense Mutation 18, Splice Site 4, Frame Shift Del 4, Intron 1, 3'Flank 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKT1 | c.967G>T p.D323Y | Missense Mutation (SNP) | VAF 7/52 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV62572120, COSV62572141; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 9/21 reads (43%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- NONO | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 4/38 reads (11%) | catalogued as rs1555949215, COSV52136099; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.430C>T p.Q144* | Nonsense Mutation (SNP) | VAF 9/49 reads (18%) | hotspot (GDC flag); catalogued as rs757274881, CM102352, COSV52662339, COSV52764890, COSV53424649; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AC136428.1 | c.178C>A p.P60T | Missense Mutation (SNP) | VAF 44/308 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as COSV101434972; called by muse, mutect2, varscan2
- ACO1 | c.2104A>T p.T702S | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT tolerated (0.41); PolyPhen benign (0.001); catalogued as COSV59377582; called by muse, mutect2, varscan2
- ADCY5 | c.1207T>A p.S403T | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.186); catalogued as COSV59195249; called by muse, mutect2, varscan2
- ADGRE2 | c.1408T>C p.S470P | Missense Mutation (SNP) | VAF 9/118 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.284); catalogued as COSV59692142; called by muse, mutect2
- ADGRE3 | c.1864G>C p.E622Q | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.206); catalogued as COSV53728740; called by muse, mutect2, varscan2
- AMBP | c.650G>A p.G217D | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.079); catalogued as rs1366286324, COSV54322580, COSV54325454; called by muse, mutect2, varscan2
- ANKRD30A | c.1909G>T p.G637W (on ENST00000611781; = p.G581W on NM_052997.2) | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.624); catalogued as COSV64605845; called by muse, mutect2, varscan2
- AOC3 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 16/169 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99520185; called by muse, mutect2, varscan2
- AOC3 | c.1373C>T p.T458M | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.471); catalogued as rs530957915, COSV53824905; called by muse, mutect2, varscan2
- AOX1 | c.2891A>T p.Y964F | Missense Mutation (SNP) | VAF 13/76 reads (17%) | SIFT tolerated (0.42); PolyPhen benign (0.06); catalogued as COSV65980558; called by muse, mutect2, varscan2
- APOB | c.8727G>C p.E2909D | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.58); PolyPhen benign (0.013); catalogued as COSV51926667; called by muse, mutect2
- ASXL3 | c.3993T>A p.S1331R | Missense Mutation (SNP) | VAF 61/172 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.021); catalogued as COSV52459687; called by muse, mutect2, varscan2
- ATG9B | c.334C>G p.P112A | Missense Mutation (SNP) | VAF 3/25 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.015); catalogued as COSV52502757; called by muse, mutect2
- ATRX | c.2494G>T p.G832C | Missense Mutation (SNP) | VAF 12/199 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.936); catalogued as COSV64872759; called by muse, mutect2
- AURKB | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV60243829; called by muse, mutect2, varscan2
- BCL10 | c.566C>G p.S189* | Nonsense Mutation (SNP) | VAF 8/34 reads (24%) | catalogued as COSV65353546; called by muse, mutect2, varscan2
- CALN1 | c.648C>A p.S216R (on ENST00000329008 / NM_001017440.3; = p.S258R on NM_031468.4) | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.003); catalogued as COSV100205160, COSV61122732; called by muse, mutect2, varscan2
- CAMSAP2 | c.3367C>G p.L1123V (on ENST00000236925 / NM_001297707.2; = p.L1112V on NM_203459.3) | Missense Mutation (SNP) | VAF 10/178 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV52667543; called by muse, mutect2
- CARD11 | c.484G>A p.E162K | Missense Mutation (SNP) | VAF 10/141 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV62716698, COSV62717202; called by muse, mutect2
- CCDC191 | c.452C>T p.T151I | Missense Mutation (SNP) | VAF 6/38 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.847); catalogued as COSV55670658; called by muse, mutect2
- CDH12 | c.1912C>T p.R638* | Nonsense Mutation (SNP) | VAF 11/65 reads (17%) | catalogued as COSV66385895; called by muse, mutect2, varscan2
- CDH22 | c.1870C>T p.P624S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.051); catalogued as COSV64836730; called by muse, mutect2, varscan2
- CDKL4 | c.721G>C p.E241Q | Missense Mutation (SNP) | VAF 4/43 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0.103); catalogued as COSV66508692; called by muse, mutect2
- CFAP46 | c.6689G>A p.R2230Q | Missense Mutation (SNP) | VAF 7/73 reads (10%) | SIFT tolerated (0.27); PolyPhen benign (0.087); catalogued as rs773804851, COSV54149769; called by muse, mutect2
- CHD8 | c.3644G>T p.G1215V (on ENST00000646647 / NM_001170629.2; = p.G936V on NM_020920.4) | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV67869865; called by muse, mutect2, varscan2
- CHPF | c.1940T>C p.F647S | Missense Mutation (SNP) | VAF 7/102 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV60533879; called by muse, mutect2
- CLCA4 | c.1687G>T p.G563C | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55366849; called by muse, varscan2
- CLMP | c.883C>T p.R295W | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.23); catalogued as rs201115327, COSV71649276; called by muse, mutect2, varscan2
- COL4A3 | c.2742G>C p.Q914H | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.001); catalogued as COSV67413599, COSV67419717; called by muse, mutect2, varscan2
- CRACD | c.737G>A p.R246K | Missense Mutation (SNP) | VAF 3/21 reads (14%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs1359771033; called by muse, mutect2
- CSMD1 | c.10131C>A p.D3377E (on ENST00000520002; = p.D3376E on NM_033225.6) | Missense Mutation (SNP) | VAF 11/24 reads (46%) | SIFT tolerated (0.08); PolyPhen benign (0.078); catalogued as COSV59292472; called by muse, mutect2, varscan2
- CTSZ | c.395G>T p.C132F | Missense Mutation (SNP) | VAF 7/57 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53882632; called by muse, mutect2, varscan2
- DCN | c.131G>A p.R44H | Missense Mutation (SNP) | VAF 18/113 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs1339258297, COSV50006279; called by muse, mutect2, varscan2
- DGKA | c.790G>T p.D264Y | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.597); catalogued as COSV59384579; called by muse, mutect2, varscan2
- DISC1 | c.268T>A p.S90T | Missense Mutation (SNP) | VAF 8/43 reads (19%) | SIFT tolerated (0.41); PolyPhen benign (0.068); catalogued as COSV54402144; called by muse, mutect2, varscan2
- DISP3 | c.242G>A p.G81D | Missense Mutation (SNP) | VAF 12/89 reads (13%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.942); catalogued as COSV53822193; called by muse, mutect2, varscan2
- DMGDH | c.1954G>A p.D652N | Missense Mutation (SNP) | VAF 11/97 reads (11%) | SIFT tolerated (0.48); PolyPhen benign (0.005); catalogued as COSV54861308; called by muse, mutect2
- DNAI2 | c.1166G>T p.R389L | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as COSV100209823, COSV56756701; called by muse, mutect2, varscan2
- DPYD | c.331G>A p.G111R | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1201456521, COSV60075790; called by muse, mutect2, varscan2
- DSCAM | c.5239G>T p.A1747S | Missense Mutation (SNP) | VAF 10/42 reads (24%) | SIFT tolerated (0.7); PolyPhen probably damaging (0.985); catalogued as COSV68022193, COSV68022448; called by muse, varscan2
- DST | c.11850G>T p.E3950D (on ENST00000361203 / NM_001374722.1; = p.E1538D on NM_015548.5) | Missense Mutation (SNP) | VAF 13/132 reads (10%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.77); catalogued as COSV55001696; called by muse, mutect2, varscan2
- DST | c.9128C>G p.S3043* | Nonsense Mutation (SNP) | VAF 7/56 reads (13%) | catalogued as COSV99757062; called by muse, mutect2, varscan2
- DST | c.8513C>T p.S2838L | Missense Mutation (SNP) | VAF 15/173 reads (9%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.027); catalogued as COSV99757064; called by muse, mutect2
- DYNC1H1 | c.5963C>T p.P1988L | Missense Mutation (SNP) | VAF 9/43 reads (21%) | SIFT tolerated (0.1); PolyPhen benign (0.259); catalogued as rs1399670309, COSV64134910; called by muse, mutect2, varscan2
- EIF3A | c.2848C>T p.L950F | Missense Mutation (SNP) | VAF 23/167 reads (14%) | SIFT tolerated (0.7); PolyPhen benign (0.052); catalogued as COSV64960674; called by muse, mutect2, varscan2
- EIF4G2 | c.1501G>A p.A501T | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT tolerated (0.54); PolyPhen benign (0.168); catalogued as COSV60596406; called by muse, mutect2, varscan2
- ENGASE | c.887C>T p.S296F | Missense Mutation (SNP) | VAF 12/149 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.761); catalogued as COSV56134563; called by muse, mutect2
- EPHB1 | c.601C>T p.Q201* | Nonsense Mutation (SNP) | VAF 34/171 reads (20%) | catalogued as COSV67655742; called by muse, mutect2, varscan2
- ERAP1 | c.1467T>A p.D489E | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT tolerated (0.55); PolyPhen benign (0.006); catalogued as COSV57085750; called by muse, mutect2
- ETNK1 | c.558-1G>T p.X186_splice | Splice Site (SNP) | VAF 12/31 reads (39%) | catalogued as COSV99860769; called by muse, mutect2, varscan2
- ETNK1 | c.558G>T p.R186S | Missense Mutation (SNP) | VAF 12/31 reads (39%) | SIFT tolerated (0.49); PolyPhen benign (0.015); catalogued as COSV99860770; called by muse, mutect2, varscan2
- EXD1 | c.848G>A p.R283H | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.162); catalogued as rs771880504, COSV59253075; called by muse, mutect2, varscan2
- FAT4 | c.13616C>A p.P4539H | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.629); catalogued as COSV58674769, COSV58688892; called by muse, mutect2
- FLNA | c.7807G>T p.E2603* (on ENST00000369850 / NM_001110556.2; = p.E2595* on NM_001456.3) | Nonsense Mutation (SNP) | VAF 8/36 reads (22%) | catalogued as COSV100774781, COSV100775287; called by muse, mutect2
- FMO1 | c.1364C>T p.T455M | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.081); catalogued as rs376397216, COSV61444477; called by muse, mutect2
- FOLH1 | c.1066T>G p.Y356D | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV57046555; called by muse, mutect2, varscan2
- GAK | c.1042C>T p.P348S | Missense Mutation (SNP) | VAF 8/48 reads (17%) | SIFT tolerated (0.48); PolyPhen benign (0.003); catalogued as COSV58503317, COSV58508176; called by muse, mutect2, varscan2
- GALNT5 | c.1353G>T p.K451N | Missense Mutation (SNP) | VAF 8/86 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.1); catalogued as COSV52036299; called by muse, mutect2
- GMIP | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.943); catalogued as rs769783652, COSV52283298; called by muse, mutect2, varscan2
- H2AC20 | c.56C>A p.S19* | Nonsense Mutation (SNP) | VAF 10/196 reads (5%) | catalogued as COSV58611425; called by muse, mutect2
- H3C3 | c.92C>T p.P31L | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.168); catalogued as rs1422878610, COSV63550732; called by muse, mutect2
- HARS1 | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV56905582, COSV56906207; called by muse, mutect2
- HGF | c.823G>T p.D275Y | Missense Mutation (SNP) | VAF 17/58 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55946341, COSV55956433; called by muse, mutect2, varscan2
- HLA-A | c.471del p.W157* | Frame Shift Del (DEL) | VAF 8/68 reads (12%) | catalogued as CM1412085; called by pindel, varscan2
- HNRNPA1 | c.1112G>C p.R371T (on ENST00000340913 / NM_031157.4; = p.R319T on NM_002136.4) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.143); catalogued as COSV52935862; called by muse, mutect2, varscan2
- HTR3A | c.804del p.N269Tfs*20 | Frame Shift Del (DEL) | VAF 6/49 reads (12%) | catalogued as rs1330890450, COSV55471054; called by mutect2, pindel, varscan2
- INSRR | c.694G>A p.E232K | Missense Mutation (SNP) | VAF 8/70 reads (11%) | SIFT tolerated (0.2); PolyPhen benign (0.196); catalogued as rs140347940; called by muse, mutect2, varscan2
- IRF5 | c.1171C>T p.P391S | Missense Mutation (SNP) | VAF 28/122 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV50856900; called by muse, mutect2, varscan2
- IRF7 | c.1426G>C p.E476Q (on ENST00000397566; = p.E463Q on NM_001572.5) | Missense Mutation (SNP) | VAF 3/46 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52752323; called by muse, mutect2
- ITGA4 | c.949G>T p.A317S | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated (0.53); PolyPhen possibly damaging (0.674); catalogued as COSV51998402; called by muse, mutect2
- KBTBD3 | c.244G>A p.E82K | Missense Mutation (SNP) | VAF 4/16 reads (25%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.702); catalogued as COSV73241268; called by muse, mutect2, varscan2
- KCNA6 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 5/33 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.33); catalogued as COSV54974371; called by muse, mutect2, varscan2
- KIF16B | c.3385C>T p.R1129C | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs767967206, COSV61702298; called by mutect2, varscan2
- KRT80 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as COSV57547917; called by muse, mutect2, varscan2
- LARGE2 | c.1894C>T p.R632C | Missense Mutation (SNP) | VAF 19/188 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs150478912; called by muse, mutect2, varscan2
- LRFN5 | c.947C>A p.P316H | Missense Mutation (SNP) | VAF 20/46 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53246439; called by muse, mutect2, varscan2
- LRP4 | c.2033G>A p.R678H | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as COSV66134504; called by muse, mutect2, varscan2
- LYNX1 | c.141G>C p.M47I | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); catalogued as COSV59988194; called by muse, mutect2
- MADD | c.2230C>T p.P744S | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.001); catalogued as COSV60621239; called by muse, mutect2, varscan2
- MAGEC1 | c.2227C>A p.P743T | Missense Mutation (SNP) | VAF 51/266 reads (19%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.641); catalogued as COSV53569247; called by muse, mutect2, varscan2
- MAGEC2 | c.613T>C p.F205L | Missense Mutation (SNP) | VAF 27/151 reads (18%) | SIFT tolerated (0.1); PolyPhen benign (0.011); catalogued as rs752666028, COSV55998284, COSV55999413; called by muse, mutect2, varscan2
- MED25 | c.801del p.V268Sfs*11 | Frame Shift Del (DEL) | VAF 10/35 reads (29%) | catalogued as COSV57204197; called by pindel, varscan2
- MINDY4 | c.1936T>G p.F646V | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.718); catalogued as rs1278587049, COSV54671977; called by muse, mutect2, varscan2
- MMP21 | c.787G>A p.D263N | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs200358739, COSV64288896; called by muse, mutect2
- MPPED2 | c.214G>T p.G72C | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.731); catalogued as COSV63896588; called by muse, mutect2, varscan2
- MRGPRX1 | c.879G>T p.R293S | Missense Mutation (SNP) | VAF 12/84 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV57106247; called by muse, mutect2, varscan2
- MRPL1 | c.722A>T p.H241L | Missense Mutation (SNP) | VAF 14/94 reads (15%) | SIFT tolerated (0.56); PolyPhen benign (0.005); catalogued as COSV59673532; called by muse, mutect2, varscan2
- MRPS5 | c.900G>T p.R300S | Missense Mutation (SNP) | VAF 15/67 reads (22%) | SIFT tolerated (0.12); PolyPhen benign (0.069); catalogued as COSV55532951; called by muse, mutect2, varscan2
- MTCH2 | c.388G>T p.A130S | Missense Mutation (SNP) | VAF 12/71 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as COSV56766623, COSV56767865; called by muse, mutect2, varscan2
- MUC16 | c.2359A>T p.N787Y | Missense Mutation (SNP) | VAF 28/158 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.183); catalogued as COSV67451302; called by muse, mutect2, varscan2
- MYBPHL | c.539A>T p.Y180F | Missense Mutation (SNP) | VAF 28/137 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV64062260; called by muse, mutect2, varscan2
- NALCN | c.2579C>A p.A860E | Missense Mutation (SNP) | VAF 10/72 reads (14%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.458); catalogued as COSV51922453, COSV99216417; called by muse, varscan2
- NAV3 | c.3751T>A p.L1251M | Missense Mutation (SNP) | VAF 3/28 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV57066430; called by muse, mutect2
- NDUFA1 | c.135G>C p.W45C | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65097137; called by muse, mutect2, varscan2
- NFKB2 | c.2203G>A p.D735N | Missense Mutation (SNP) | VAF 10/75 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as COSV50042425; called by muse, mutect2, varscan2
- NIPAL4 | c.248C>A p.S83Y | Missense Mutation (SNP) | VAF 10/95 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.007); catalogued as COSV61729506; called by muse, mutect2, varscan2
- NODAL | c.370G>A p.A124T | Missense Mutation (SNP) | VAF 18/71 reads (25%) | SIFT tolerated (0.53); PolyPhen benign (0.129); catalogued as COSV54660714; called by muse, mutect2, varscan2
- NPM1 | c.819G>C p.K273N | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.08); PolyPhen benign (0.167); catalogued as COSV51548799; called by muse, varscan2
- NPSR1 | c.625C>A p.P209T | Missense Mutation (SNP) | VAF 16/173 reads (9%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.9); catalogued as COSV100706516, COSV104416690; called by muse, mutect2
- NUDT1 | c.271G>A p.G91S (on ENST00000397048 / NM_198952.1; = p.G68S on NM_002452.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs1485939392, COSV56125504; called by muse, mutect2, varscan2
- OBSCN | c.3336G>C p.K1112N | Missense Mutation (SNP) | VAF 12/152 reads (8%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.995); catalogued as COSV52749378, COSV52772272; called by muse, mutect2
- OBSCN | c.12529G>T p.E4177* | Nonsense Mutation (SNP) | VAF 35/82 reads (43%) | catalogued as COSV52749412; called by muse, mutect2, varscan2
- OR10G7 | c.386T>A p.L129H | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57865984; called by muse, mutect2, varscan2
- OR13C5 | c.303G>A p.M101I | Missense Mutation (SNP) | VAF 10/134 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.303); catalogued as COSV66164351; called by muse, mutect2
- OR13C8 | c.364C>T p.R122C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT tolerated (0.05); PolyPhen benign (0.155); catalogued as rs79042036; called by muse, mutect2, varscan2
- OR4N2 | c.545C>T p.P182L | Missense Mutation (SNP) | VAF 40/214 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.151); catalogued as rs757156304, COSV60050367; called by muse, varscan2
- OR4Q3 | c.677C>A p.S226Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59177587, COSV59180701; called by muse, mutect2
- OR6K3 | c.667A>G p.I223V (on ENST00000368146; = p.I207V on NM_001005327.2) | Missense Mutation (SNP) | VAF 16/138 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.013); catalogued as rs1364610188, COSV63745386; called by muse, mutect2, varscan2
- OR6T1 | c.670A>T p.T224S | Missense Mutation (SNP) | VAF 6/39 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.874); catalogued as COSV58305980; called by muse, mutect2, varscan2
- OR8D1 | c.663C>G p.I221M | Missense Mutation (SNP) | VAF 9/29 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63441806; called by muse, mutect2, varscan2
- PCDH15 | c.5206C>A p.H1736N | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.11); PolyPhen probably damaging (0.943); catalogued as COSV57271737; called by muse, mutect2, varscan2
- PCDHA12 | c.772G>A p.D258N | Missense Mutation (SNP) | VAF 12/88 reads (14%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.6); catalogued as COSV56482900; called by muse, mutect2, varscan2
- PCLO | c.11400C>A p.Y3800* | Nonsense Mutation (SNP) | VAF 14/84 reads (17%) | catalogued as COSV100433916, COSV61621121; called by muse, mutect2, varscan2
- PDE5A | c.464T>A p.L155* | Nonsense Mutation (SNP) | VAF 5/46 reads (11%) | catalogued as COSV53346018; called by muse, mutect2, varscan2
- PHF2 | c.1327G>T p.E443* | Nonsense Mutation (SNP) | VAF 13/27 reads (48%) | catalogued as COSV63679191; called by muse, mutect2, varscan2
- PLCB1 | c.2142G>T p.K714N | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.414); catalogued as COSV62041817; called by muse, mutect2, varscan2
- PLK3 | c.1376A>T p.E459V | Missense Mutation (SNP) | VAF 36/164 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.053); catalogued as COSV59499253; called by muse, mutect2, varscan2
- PPARD | c.237C>G p.D79E | Missense Mutation (SNP) | VAF 5/68 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.401); catalogued as COSV61098997; called by muse, mutect2
- PPP1R12C | c.982C>T p.R328W | Missense Mutation (SNP) | VAF 28/135 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as rs202008761, COSV54736393; called by muse, mutect2, varscan2
- PRKDC | c.5326G>A p.E1776K | Missense Mutation (SNP) | VAF 7/106 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.351); catalogued as COSV58046059; called by muse, mutect2
- PRSS22 | c.800C>G p.A267G | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50721156, COSV50723403; called by muse, mutect2, varscan2
- PTCH1 | c.1123C>T p.H375Y | Missense Mutation (SNP) | VAF 10/64 reads (16%) | SIFT tolerated (0.27); PolyPhen benign (0.086); catalogued as rs374145534; called by muse, mutect2, varscan2
- PTGDR | c.151C>T p.R51W | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.438); catalogued as rs572021133, COSV60093279; called by muse, mutect2
- PUM1 | c.280G>T p.G94W | Missense Mutation (SNP) | VAF 18/65 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV57082540; called by muse, mutect2, varscan2
- PXDN | c.4112C>T p.S1371L | Missense Mutation (SNP) | VAF 5/77 reads (6%) | SIFT tolerated (0.36); PolyPhen benign (0); catalogued as COSV53228482; called by muse, mutect2
- RAG1 | c.1687G>T p.D563Y | Missense Mutation (SNP) | VAF 9/51 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55024216; called by muse, mutect2, varscan2
- RNF17 | c.2684A>G p.H895R | Missense Mutation (SNP) | VAF 4/23 reads (17%) | SIFT tolerated (0.26); PolyPhen benign (0); catalogued as COSV55035651; called by mutect2, varscan2
- RRBP1 | c.289C>T p.R97* | Nonsense Mutation (SNP) | VAF 5/25 reads (20%) | catalogued as rs774473221, COSV55696786; called by muse, mutect2, varscan2
- RYK | c.397A>G p.M133V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.025); catalogued as rs750477962, COSV99938467; called by mutect2, varscan2
- SHOC1 | c.3395C>T p.A1132V | Missense Mutation (SNP) | VAF 7/43 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.133); catalogued as COSV59498415; called by muse, mutect2, varscan2
- SI | c.3361G>T p.A1121S | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT tolerated (0.67); PolyPhen benign (0.015); catalogued as COSV52267393, COSV52269060; called by mutect2, varscan2
- SI | c.407C>A p.P136H | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.882); catalogued as COSV52269081, COSV52288524; called by muse, varscan2
- SIX2 | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 17/109 reads (16%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.704); catalogued as COSV57390257; called by muse, mutect2, varscan2
- SLC12A5 | c.386C>T p.P129L (on ENST00000454036 / NM_001134771.2; = p.P106L on NM_020708.5) | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV54789861; called by muse, mutect2, varscan2
- SLC43A1 | c.807G>C p.E269D | Missense Mutation (SNP) | VAF 8/38 reads (21%) | SIFT tolerated (0.14); PolyPhen benign (0.02); catalogued as COSV53557861, COSV53561490; called by muse, mutect2, varscan2
- SLC4A1 | c.451G>T p.E151* | Nonsense Mutation (SNP) | VAF 9/31 reads (29%) | catalogued as COSV52258804, COSV52262984; called by muse, mutect2, varscan2
- SMYD4 | c.742G>A p.V248I | Missense Mutation (SNP) | VAF 16/125 reads (13%) | SIFT tolerated (0.57); PolyPhen benign (0.044); catalogued as rs779364908, COSV59710821; called by muse, mutect2, varscan2
- SNURF | c.207A>T p.R69S | Missense Mutation (SNP) | VAF 6/42 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.849); catalogued as rs1460921830, COSV57594602; called by muse, mutect2, varscan2
- SPATA31E1 | c.2729G>A p.S910N | Missense Mutation (SNP) | VAF 8/50 reads (16%) | SIFT tolerated (0.07); PolyPhen benign (0.421); catalogued as rs981366015, COSV57789969; called by muse, mutect2, varscan2
- SPINDOC | c.481G>A p.D161N | Missense Mutation (SNP) | VAF 11/103 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.203); catalogued as COSV53692076; called by muse, mutect2, varscan2
- STAG2 | c.661C>A p.L221M | Missense Mutation (SNP) | VAF 21/124 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54349966, COSV54352668; called by muse, mutect2, varscan2
- STAG3 | c.1073A>G p.E358G | Missense Mutation (SNP) | VAF 12/139 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.011); catalogued as COSV57928168, COSV57929244; called by muse, mutect2
- SUPT5H | c.1010A>G p.Q337R | Missense Mutation (SNP) | VAF 18/87 reads (21%) | SIFT tolerated (0.51); PolyPhen possibly damaging (0.542); catalogued as COSV63238610; called by muse, mutect2, varscan2
- SYNGAP1 | c.1522G>C p.D508H | Missense Mutation (SNP) | VAF 5/134 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV53378828; called by muse, mutect2
- TEX13B | c.800G>A p.C267Y | Missense Mutation (SNP) | VAF 22/155 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.162); catalogued as COSV57202277; called by muse, mutect2, varscan2
- THNSL2 | c.1105G>T p.V369L | Missense Mutation (SNP) | VAF 13/59 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.132); catalogued as COSV59082163; called by muse, mutect2, varscan2
- TLL1 | c.633-1G>C p.X211_splice | Splice Site (SNP) | VAF 8/67 reads (12%) | catalogued as COSV50264529; called by muse, mutect2, varscan2
- TMEM132E | c.1169C>G p.S390C (on ENST00000321639; = p.S480C on NM_001304438.2) | Missense Mutation (SNP) | VAF 4/38 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV58695194, COSV58700681; called by muse, mutect2
- TMEM255B | c.534T>A p.Y178* | Nonsense Mutation (SNP) | VAF 6/27 reads (22%) | catalogued as COSV64703538; called by muse, mutect2, varscan2
- TRPC5 | c.1896+1G>A p.X632_splice | Splice Site (SNP) | VAF 30/157 reads (19%) | catalogued as rs765267726, COSV53285878; called by muse, mutect2, varscan2
- TRPS1 | c.634C>A p.P212T (on ENST00000220888 / NM_001330599.2; = p.P225T on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/161 reads (12%) | SIFT tolerated, low confidence (0.92); PolyPhen benign (0); catalogued as COSV55229850; called by muse, mutect2, varscan2
- TTN | c.78487G>A p.E26163K (on ENST00000591111; = p.E18739K on NM_003319.4) | Missense Mutation (SNP) | VAF 14/50 reads (28%) | PolyPhen probably damaging (0.997); catalogued as rs759095633, COSV59924104; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- UMOD | c.1799A>T p.N600I | Missense Mutation (SNP) | VAF 23/57 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.947); catalogued as COSV56774171, COSV56780322; called by muse, mutect2, varscan2
- UNC79 | c.4258C>A p.L1420M (on ENST00000393151 / NM_001346218.2; = p.L1243M on NM_020818.5) | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.042); catalogued as COSV56377878; called by muse, mutect2, varscan2
- USP28 | c.2291C>T p.A764V | Missense Mutation (SNP) | VAF 31/144 reads (22%) | SIFT tolerated (0.3); PolyPhen benign (0.037); catalogued as rs780410860, COSV50156636; called by muse, mutect2, varscan2
- VARS2 | c.2466+1G>C p.X822_splice | Splice Site (SNP) | VAF 10/84 reads (12%) | catalogued as COSV58911563; called by muse, mutect2, varscan2
- VPS13D | c.6380C>T p.S2127F | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.7); PolyPhen benign (0.001); catalogued as COSV50625440; called by muse, mutect2
- WDR6 | c.2288C>G p.S763* | Nonsense Mutation (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100556406, COSV58243966, COSV58244167; called by muse, mutect2, varscan2
- XRN1 | c.2777A>T p.Y926F | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.333); catalogued as COSV53808943; called by muse, mutect2
- ZBTB21 | c.2911G>T p.E971* | Nonsense Mutation (SNP) | VAF 10/91 reads (11%) | catalogued as COSV60403366, COSV60403954; called by muse, mutect2
- ZBTB21 | c.1846G>T p.E616* | Nonsense Mutation (SNP) | VAF 10/92 reads (11%) | catalogued as COSV60403372, COSV60404065; called by muse, mutect2
- ZBTB3 | c.115C>G p.R39G | Missense Mutation (SNP) | VAF 3/43 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV67360784, COSV67361584; called by muse, mutect2
- ZEB1 | c.3028C>A p.H1010N | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV58038599; called by muse, mutect2, varscan2
- ZNF254 | c.542C>T p.S181F | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs1342762909, COSV100741569, COSV61641339; called by muse, mutect2, varscan2
- ZNF507 | c.2073C>G p.H691Q | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV61330327; called by muse, mutect2, varscan2
- ZNF618 | c.785G>T p.G262V (on ENST00000374126 / NM_001318042.2; = p.G250V on NM_133374.2) | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV55917659; called by muse, mutect2
- ZNF677 | c.416C>G p.S139C | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.867); catalogued as COSV61719568; called by muse, mutect2, varscan2
- ZNF718 | c.843A>C p.K281N | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.931); catalogued as COSV68140318, COSV68140496; called by muse, mutect2, varscan2
- ZNFX1 | c.1537G>C p.E513Q | Missense Mutation (SNP) | VAF 5/64 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65574118; called by muse, mutect2
- ERAL1 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0); called by muse, mutect2
- IGHV3-48 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 8/131 reads (6%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.709); called by muse, mutect2
- IGLV2-33 | c.209A>G p.Y70C | Missense Mutation (SNP) | VAF 79/314 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- ZNF208 | c.3762del p.K1254Nfs*104 | Frame Shift Del (DEL) | VAF 10/54 reads (19%) | called by mutect2, pindel, varscan2
- ZNF276 | c.1194C>A p.S398R (on ENST00000443381 / NM_001113525.2; = p.S323R on NM_152287.4) | Missense Mutation (SNP) | VAF 14/110 reads (13%) | SIFT tolerated (0.67); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- ABCC4 | c.3174G>A p.L1058= | Silent (SNP) | VAF 7/97 reads (7%) | catalogued as rs1164440774, COSV65310369; called by muse, mutect2
- ADAMTS5 | c.1593C>A p.T531= | Silent (SNP) | VAF 7/64 reads (11%) | catalogued as rs1334384950, COSV53176566; called by muse, mutect2, varscan2
- ADGRA3 | c.3228C>T p.P1076= | Silent (SNP) | VAF 5/32 reads (16%) | catalogued as rs767346100, COSV51560806; called by muse, mutect2, varscan2
- APOB | c.13584C>T p.Y4528= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs1490771906, COSV51926654; called by muse, mutect2, varscan2
- ARMC6 | c.1434C>T p.A478= (on ENST00000392336; = p.A453= on NM_033415.4) | Silent (SNP) | VAF 12/79 reads (15%) | catalogued as COSV54180548; called by muse, mutect2, varscan2
- BRCC3 | c.930A>G p.Q310= | Silent (SNP) | VAF 13/63 reads (21%) | catalogued as COSV57461986; called by muse, mutect2, varscan2
- CACNG3 | c.399C>T p.N133= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as rs147734423; called by muse, mutect2, varscan2
- CHL1 | c.993T>C p.P331= (on ENST00000397491 / NM_001253387.1; = p.P347= on NM_006614.4) | Silent (SNP) | VAF 20/134 reads (15%) | catalogued as COSV56588295; called by muse, mutect2, varscan2
- CRNN | c.837C>T p.S279= | Silent (SNP) | VAF 58/521 reads (11%) | catalogued as COSV55121055; called by muse, mutect2, varscan2
- DDI1 | c.921T>A p.I307= | Silent (SNP) | VAF 9/52 reads (17%) | catalogued as COSV56370787; called by muse, mutect2, varscan2
- DHRS9 | c.171C>T p.I57= | Silent (SNP) | VAF 21/62 reads (34%) | catalogued as rs754346896, COSV59138981; called by muse, mutect2, varscan2
- DMD | c.5952G>A p.V1984= | Silent (SNP) | VAF 5/22 reads (23%) | catalogued as COSV100820129; called by muse, mutect2, varscan2
- ERH | c.282C>T p.L94= | Silent (SNP) | VAF 21/85 reads (25%) | catalogued as rs1232614651, COSV53680309; called by muse, mutect2, varscan2
- ESRRG | c.240C>T p.D80= | Silent (SNP) | VAF 22/109 reads (20%) | catalogued as rs767510877, COSV63151988, COSV63165599; called by muse, mutect2, varscan2
- FAM171A1 | c.1158G>A p.E386= | Silent (SNP) | VAF 9/48 reads (19%) | catalogued as rs759176110, COSV65314142; called by muse, mutect2, varscan2
- FAT3 | c.8721G>C p.T2907= | Silent (SNP) | VAF 12/109 reads (11%) | catalogued as COSV53133979, COSV99966893; called by muse, varscan2
- FKBP14 | c.444T>C p.D148= | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV56107011; called by muse, mutect2, varscan2
- HADH | c.378G>A p.V126= | Silent (SNP) | VAF 49/92 reads (53%) | catalogued as COSV58847379; called by muse, mutect2, varscan2
- HCN1 | c.2337G>T p.L779= | Silent (SNP) | VAF 8/51 reads (16%) | catalogued as COSV57497454; called by muse, mutect2, varscan2
- HGFAC | c.1824C>T p.G608= | Silent (SNP) | VAF 17/98 reads (17%) | catalogued as rs747553396, COSV66976693; called by muse, mutect2, varscan2
- IGKV1D-17 | c.126C>A p.T42= | Silent (SNP) | VAF 22/394 reads (6%) | called by muse, mutect2
- IL17A | c.174C>T p.T58= | Silent (SNP) | VAF 17/165 reads (10%) | catalogued as COSV60684072; called by muse, mutect2, varscan2
- INF2 | c.489C>T p.D163= | Silent (SNP) | VAF 8/61 reads (13%) | catalogued as rs769080446, COSV53030595; ClinVar: likely benign; called by muse, mutect2, varscan2
- KIAA0753 | c.390G>A p.Q130= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV63816917; called by muse, mutect2
- KIF19 | c.2355C>A p.A785= | Silent (SNP) | VAF 11/104 reads (11%) | catalogued as rs747299635, COSV100739086, COSV63431125; called by muse, mutect2, varscan2
- KIF21A | c.192C>T p.I64= | Silent (SNP) | VAF 10/64 reads (16%) | catalogued as COSV62768324; called by muse, mutect2, varscan2
- MRPL39 | c.313C>T p.L105= | Silent (SNP) | VAF 5/30 reads (17%) | catalogued as rs748073707, COSV56260081; called by muse, mutect2, varscan2
- MYBBP1A | c.2757C>T p.T919= | Silent (SNP) | VAF 15/118 reads (13%) | catalogued as rs769485013, COSV54594592; ClinVar: likely benign; called by muse, mutect2, varscan2
- NFYC | c.279C>T p.R93= | Silent (SNP) | VAF 32/91 reads (35%) | catalogued as COSV58126182; called by muse, mutect2, varscan2
- NPSR1 | c.624C>A p.T208= | Silent (SNP) | VAF 14/172 reads (8%) | catalogued as COSV100706511; called by muse, mutect2
- NT5C3A | c.561C>T p.L187= (on ENST00000610140 / NM_001374335.1; = p.L153= on NM_016489.13) | Silent (SNP) | VAF 38/87 reads (44%) | catalogued as COSV54237234; called by muse, mutect2, varscan2
- NUAK2 | c.69G>T p.L23= | Silent (SNP) | VAF 8/62 reads (13%) | catalogued as COSV65680964; called by muse, mutect2, varscan2
- OPA1 | c.2103A>T p.S701= (on ENST00000361510 / NM_130837.3; = p.S646= on NM_015560.3) | Silent (SNP) | VAF 4/13 reads (31%) | catalogued as COSV62479344; called by muse, mutect2, varscan2
- OR4A15 | c.792C>A p.P264= | Silent (SNP) | VAF 39/185 reads (21%) | catalogued as COSV59033942, COSV59035640; called by muse, mutect2, varscan2
- OR6V1 | c.150C>T p.D50= | Silent (SNP) | VAF 65/282 reads (23%) | catalogued as rs909750404, COSV69237000; called by muse, mutect2, varscan2
- PTCHD4 | c.1497G>T p.S499= | Silent (SNP) | VAF 19/44 reads (43%) | catalogued as COSV59779646; called by muse, mutect2, varscan2
- RALYL | c.120C>A p.A40= | Silent (SNP) | VAF 19/45 reads (42%) | catalogued as rs267602019, COSV72818224; called by muse, mutect2, varscan2
- RELT | c.960C>T p.P320= | Silent (SNP) | VAF 8/59 reads (14%) | catalogued as COSV99292929; called by muse, mutect2, varscan2
- RS1 | c.303C>A p.A101= | Silent (SNP) | VAF 16/77 reads (21%) | catalogued as COSV66105969; called by muse, mutect2, varscan2
- SAXO1 | c.738C>A p.G246= | Silent (SNP) | VAF 20/57 reads (35%) | catalogued as COSV65868786; called by muse, mutect2, varscan2
- SIGLEC11 | c.2067G>A p.E689= | Silent (SNP) | VAF 6/23 reads (26%) | catalogued as COSV68567533; called by muse, mutect2, varscan2
- SMG6 | c.1071A>G p.E357= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV53963994, COSV53969880; called by muse, mutect2, varscan2
- SNW1 | c.1101G>C p.R367= | Silent (SNP) | VAF 14/101 reads (14%) | catalogued as COSV55053446; called by muse, mutect2, varscan2
- SPAG5 | c.75T>A p.P25= | Silent (SNP) | VAF 10/51 reads (20%) | catalogued as COSV58800418; called by muse, mutect2, varscan2
- SRRT | c.1428A>G p.K476= | Silent (SNP) | VAF 14/128 reads (11%) | catalogued as COSV53815601; called by muse, mutect2, varscan2
- TIMP4 | c.663C>T p.I221= | Silent (SNP) | VAF 10/96 reads (10%) | catalogued as rs1340979729, COSV55138724; called by muse, mutect2, varscan2
- TRPS1 | c.3573A>G p.V1191= (on ENST00000220888 / NM_001330599.2; = p.V1204= on NM_014112.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 13/55 reads (24%) | catalogued as rs890303557, COSV55227228, COSV55229832; called by muse, mutect2, varscan2
- TTC38 | c.855C>T p.A285= | Silent (SNP) | VAF 9/27 reads (33%) | catalogued as rs1343065143, COSV66843736; called by muse, mutect2, varscan2
- XIRP2 | c.147G>A p.E49= | Silent (SNP) | VAF 7/49 reads (14%) | catalogued as COSV54687112; called by muse, mutect2, varscan2
- ZNF496 | c.234G>A p.K78= | Silent (SNP) | VAF 11/111 reads (10%) | catalogued as COSV54174339; called by muse, mutect2, varscan2
- ZNF883 | c.504A>G p.L168= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV71308926; called by muse, mutect2
- DENND10P1 | n.720G>A | RNA (SNP) | VAF 14/71 reads (20%) | called by muse, mutect2, varscan2
- NDUFA6 | c.-10del | 5'UTR (DEL) | VAF 37/204 reads (18%) | called by mutect2, pindel, varscan2
- TRIM24 | c.364+282_364+285del | Intron (DEL) | VAF 11/32 reads (34%) | called by mutect2, pindel, varscan2
- TRPV2 | chr17:16439217 G>C | 3'Flank (SNP) | VAF 9/62 reads (15%) | called by muse, mutect2, varscan2
- ZNF99 | c.*93G>T | 3'UTR (SNP) | VAF 7/46 reads (15%) | catalogued as COSV68054995; called by muse, mutect2, varscan2
